Gene-level copy-number profile of tumor specimen AP-F595-DT from APOLLO case AP-F595, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-F595-DT: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d48a863-1d08-488c-88b4-13b2990d831d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-F595-AL (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/7ecc1102-2e51-4400-b2eb-0c581dc0488f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 141; copy number 2: 19,446; copy number 3: 8,515; copy number 4: 23,969; copy number 5: 3,644; copy number 6: 1,642; copy number 7: 804; copy number 8: 358; copy number 9: 48; copy number 10: 71; copy number 11: 63; copy number 12: 108; copy number 15: 62; copy number 22: 4; copy number 45: 22; copy number 58: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr20:14,554,384–14,758,056, 2 genes (within-gene range 0–6): MACROD2-IT1, RPS10P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 380 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,641–54,295,272, 2 genes, copy number 45 (within-gene range 8–45): FIP1L1, AC058822.1.
- chr4:53,659,208–59,630,324, 101 genes, copy number 9–58 (within-gene range 8–58) (broad region; genes not listed).
- chr11:10,541,258–15,247,208, 82 genes, copy number 9–11 (broad region; genes not listed).
- chr11:35,251,205–35,918,739, 11 genes, copy number 12: SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1.
- chr18:74,211,391–80,247,514, 117 genes, copy number 10–12 (broad region; genes not listed).
- chr19:43,872,365–45,038,198, 67 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
